Gene-level copy-number profile of tumor specimen ALCH-B77F-TTP1-A from ALCHEMIST case ALCH-B77F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.2 years (27,483 days).
Specimen ALCH-B77F-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 002d0980-a46c-4dc3-ab32-4ae2130d3eb9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B77F-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/37fc8368-7f3c-4826-802c-093f4b560aae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 5,832; copy number 2: 52,444; copy number 3: 468; copy number 4: 144; copy number 7: 1; copy number 9: 2; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:117,542,445–117,549,546, 1 gene (within-gene range 0–2): EMX2.
- chr15:78,759,206–78,811,464, 1 gene (within-gene range 0–2): ADAMTS7.
- chr16:88,881,038–88,887,136, 1 gene (within-gene range 0–2): AC092384.2.
- chr19:40,348,456–40,414,793, 5 genes (within-gene range 0–2): PLD3, AC118344.2, MIR6796, HIPK4, PRX.
- chr19:48,968,130–49,015,970, 3 genes: GYS1, RUVBL2, MIR6798.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,087,351–242,088,457, 1 gene, copy number 7: AC093642.2.
- chr22:18,906,238–18,947,741, 3 genes, copy number 9–11 (within-gene range 2–11): AC007326.4, PRODH, AC007326.5.

Autosomal genes at a single copy (total copy number 1): 2,988. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
